Gene-level copy-number profile of tumor specimen CUPP-B3BN-TTM1-A from CCG case CUPP-B3BN, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, malignant, uncertain whether primary or metastatic; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IV; Age at diagnosis: 79.6 years (29,079 days).
Specimen CUPP-B3BN-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 968e5ab0-5a1c-48e4-8088-61a6ffb3477a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B3BN-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/404f6013-5364-4922-b1ea-5ace7625099c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 9,980; copy number 2: 46,720; copy number 3: 1,864; copy number 4: 287; copy number 5: 18; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,384,059–75,580,199, 10 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15.
- chr6:32,148,359–32,195,523, 14 genes (within-gene range 0–1): PRRT1, AL662884.4, AL662884.3, PPT2, PPT2-EGFL8, EGFL8, AGPAT1, MIR6721, RNF5, MIR6833, AGER, AL662884.1, PBX2, GPSM3.
- chr10:87,994,618–88,779,626, 12 genes: AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN.
- chr11:1,734,821–1,764,573, 4 genes (within-gene range 0–1): AC068580.4, CTSD, AC068580.3, AC068580.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene, copy number 6: MIR5692C1.
- chr6:41,905,354–42,693,505, 18 genes, copy number 5: MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1, AL591473.1, UBR2, RNU6-890P.

Autosomal genes at a single copy (total copy number 1): 7,125. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
